CCDI case PBCEZB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a99c2d6d-6c8b-45da-bc9b-95ade6c64986

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Tumor cells, uncertain whether benign or malignant: ICD-O-3 morphology code: 8001/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.4 years (1,592 days).

Biospecimens (4 samples)
- Sample 0DQHAG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DQHB7, 0DQHBH (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQMPP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
